Somatic mutation profile of tumor specimen TCGA-DK-AA6S-01A (aliquot TCGA-DK-AA6S-01A-21D-A391-08) from TCGA case TCGA-DK-AA6S, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 60.3 years (22,027 days).
Specimen TCGA-DK-AA6S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfe3da64-c5a6-43a3-bac6-20a2a2f870e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-AA6S-10A (Blood Derived Normal), aliquot TCGA-DK-AA6S-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f49c7b15-ca19-4cc1-9cf5-539881a1f94c

The open-access MAF lists 622 somatic variants for this specimen: 460 protein-altering or splice-affecting, 152 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 386, Silent 152, Nonsense Mutation 45, Splice Region 8, Splice Site 7, Frame Shift Del 6, Intron 4, Translation Start Site 4, 3'UTR 3, Frame Shift Ins 2, Nonstop Mutation 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 11/22 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs121913381, CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1558G>A p.D520N (on ENST00000281708 / NM_001349798.2; = p.D440N on NM_018315.5) | Missense Mutation (SNP) | VAF 32/85 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895090, COSV55923112, COSV55961967; called by muse, mutect2, varscan2
- AARS1 | c.1806G>C p.M602I | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55749660; called by muse, mutect2, varscan2
- ABCC10 | c.379C>G p.H127D (on ENST00000372530 / NM_001198934.2; = p.H84D on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV55086653; called by muse, mutect2, varscan2
- ABCC10 | c.1332C>G p.I444M (on ENST00000372530 / NM_001198934.2; = p.I401M on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV55094151; called by muse, varscan2
- ACOX2 | c.732G>C p.K244N | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV57151010; called by muse, mutect2, varscan2
- ACTR6 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 30/81 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as COSV51841619, COSV51841650; called by muse, mutect2, varscan2
- AGAP2 | c.2085G>T p.W695C (on ENST00000547588 / NM_001122772.2; = p.W359C on NM_014770.4) | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57732241; called by muse, mutect2, varscan2
- AGR3 | c.501A>C p.*167Yext*26 | Nonstop Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as rs1368913990, COSV100124055; called by muse, mutect2, varscan2
- AHNAK2 | c.14312G>A p.R4771Q | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs755301339, COSV60931453; called by muse, mutect2, varscan2
- AKAP3 | c.1952C>G p.S651C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as rs1182460628, COSV99962413, COSV99962459; called by muse, mutect2
- AKAP9 | c.9103G>A p.D3035N (on ENST00000359028; = p.D3011N on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs1287618539, COSV62358447; called by muse, mutect2, varscan2
- AL035461.3 | c.2629G>C p.D877H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101125867; called by muse, mutect2, varscan2
- ANK2 | c.11002G>C p.E3668Q | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52158595, COSV52189713; called by muse, mutect2, varscan2
- ANK3 | c.285G>C p.Q95H | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV55083058; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4123C>T p.Q1375* | Nonsense Mutation (SNP) | VAF 51/103 reads (50%) | catalogued as rs1256555606, COSV99783988; called by muse, mutect2, varscan2
- ANKLE2 | c.2093G>C p.R698T | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV61711818; called by muse, mutect2, varscan2
- ANKRD2 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV53969759; called by muse, varscan2
- ANKRD26 | c.128G>C p.R43P | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs1454901004, COSV65798753; called by muse, mutect2, varscan2
- ANKRD36 | c.346C>T p.L116F | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV70745884; called by muse, mutect2, varscan2
- ANO6 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV57668162; called by muse, mutect2, varscan2
- AP4E1 | c.1690C>T p.Q564* | Nonsense Mutation (SNP) | VAF 35/97 reads (36%) | catalogued as COSV99956961; called by muse, mutect2, varscan2
- ARFGEF2 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV100903937, COSV64215293; called by muse, mutect2, varscan2
- ARHGAP12 | c.1457G>A p.W486* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV100260776; called by muse, mutect2, varscan2
- ARHGAP20 | c.3186G>C p.E1062D | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV52809152, COSV52819517; called by muse, mutect2, varscan2
- ARR3 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100330926; called by muse, mutect2
- ATF6B | c.92-1G>C p.X31_splice | Splice Site (SNP) | VAF 13/28 reads (46%) | catalogued as COSV64322878; called by muse, mutect2, varscan2
- ATF6B | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as COSV64322880; called by muse, mutect2, varscan2
- ATN1 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV63113131; called by muse, mutect2, varscan2
- ATN1 | c.618C>G p.F206L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); catalogued as COSV63113133; called by muse, varscan2
- ATN1 | c.686C>G p.S229C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.431); catalogued as COSV63113140; called by muse, varscan2
- ATP10B | c.4187C>T p.S1396L | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV59165167; called by muse, mutect2, varscan2
- ATP2A2 | c.2110G>C p.V704L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57875091, COSV57876370; called by muse, varscan2
- AZIN1 | c.1218G>A p.M406I | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV61481360; called by muse, mutect2, varscan2
- B3GALT1 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as rs779917122, COSV59909914; called by muse, mutect2, varscan2
- B3GALT5 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV100563411, COSV58200670; called by muse, mutect2, varscan2
- BAHCC1 | c.5896G>C p.D1966H | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs1555658531, COSV100311928; called by muse, mutect2
- BBS2 | c.1605C>G p.F535L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.101); catalogued as rs771778427, COSV55328710; called by muse, mutect2, varscan2
- BCAR1 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs866508880, COSV50805330; called by muse, mutect2, varscan2
- BCAS3 | c.1808-1G>C p.X603_splice (on ENST00000390652 / NM_001353144.2; = p.X588_splice on NM_017679.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 66/142 reads (46%) | catalogued as COSV66782667; called by muse, mutect2, varscan2
- BDKRB1 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 33/72 reads (46%) | catalogued as COSV99387973; called by muse, mutect2, varscan2
- BFAR | c.1256del p.C419Sfs*39 | Frame Shift Del (DEL) | VAF 34/127 reads (27%) | catalogued as COSV55494564; called by mutect2, pindel, varscan2
- BMPR2 | c.1703C>A p.S568Y | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV65813596; called by muse, mutect2, varscan2
- BRCC3 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.292); catalogued as rs1557296634, COSV100341719; called by muse, mutect2, varscan2
- BRIP1 | c.3151G>A p.D1051N | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.018); catalogued as COSV52009263; called by muse, mutect2, varscan2
- BRSK2 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.211); catalogued as rs1239309324, COSV57543254, COSV57549269; called by muse, mutect2, varscan2
- BTG2 | c.279C>G p.H93Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV51858334; called by muse, mutect2, varscan2
- BUB1 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 22/96 reads (23%) | catalogued as COSV57067123; called by muse, mutect2, varscan2
- C20orf194 | c.2900C>T p.S967L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as COSV52703274; called by muse, mutect2, varscan2
- C2CD2L | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV60884834; called by muse, mutect2, varscan2
- C3AR1 | c.299C>G p.S100C | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV50825229; called by muse, mutect2, varscan2
- C3orf20 | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 33/101 reads (33%) | catalogued as COSV99514351; called by muse, varscan2
- C5orf34 | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as COSV60932091; called by muse, mutect2, varscan2
- C6orf118 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100024856; called by muse, mutect2
- CABS1 | c.829G>C p.D277H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV56733125; called by muse, mutect2, varscan2
- CACNA1A | c.5833G>C p.D1945H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1193365931, COSV64195362; called by muse, mutect2, varscan2
- CACNA1D | c.4042C>G p.Q1348E (on ENST00000350061 / NM_001128840.3; = p.Q1368E on NM_000720.4) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV55465650; called by muse, mutect2, varscan2
- CACNA2D1 | c.898G>C p.D300H | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV100666598, COSV62392991; called by muse, mutect2, varscan2
- CAPZB | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51652182; called by muse, mutect2, varscan2
- CARS2 | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57289289; called by muse, mutect2, varscan2
- CATSPERD | c.126G>A p.G42= | Splice Region (SNP) | VAF 34/157 reads (22%) | catalogued as rs1325551167, COSV62263386; called by muse, mutect2, varscan2
- CCDC18 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58147870; called by muse, mutect2, varscan2
- CCDC180 | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.227); catalogued as COSV63832261, COSV63835673; called by muse, mutect2, varscan2
- CCDC96 | c.1152G>C p.Q384H | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.218); catalogued as COSV59509611; called by muse, mutect2, varscan2
- CCNA1 | c.1010T>A p.F337Y | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs761107193, COSV55224035; called by muse, mutect2, varscan2
- CCNT1 | c.1552C>T p.H518Y | Missense Mutation (SNP) | VAF 98/299 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV56066193; called by muse, mutect2, varscan2
- CCR5 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 126/398 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as COSV52753132; called by muse, varscan2
- CCT6A | c.1156C>G p.Q386E | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV51907841; called by muse, varscan2
- CD163 | c.2474G>A p.R825K | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV63137385; called by muse, mutect2, varscan2
- CD163L1 | c.3448G>A p.E1150K | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.079); catalogued as COSV58025105; called by muse, mutect2
- CDC6 | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV52929765; called by muse, mutect2, varscan2
- CDH17 | c.2074G>T p.D692Y | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50342154; called by muse, mutect2, varscan2
- CDHR5 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs571458654, COSV51563914; called by muse, mutect2, varscan2
- CDK13 | c.997C>G p.Q333E | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.258); catalogued as rs1480119569, COSV99475896; called by muse, mutect2, varscan2
- CDK9 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1176271577, COSV64724218; called by muse, mutect2, varscan2
- CELSR3 | c.1816G>T p.A606S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.048); catalogued as COSV51155628; called by muse, mutect2, varscan2
- CEP112 | c.2733G>T p.L911F (on ENST00000392769 / NM_001353127.1; = p.L167F on NM_001037325.3) | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV58068408; called by muse, mutect2, varscan2
- CEP170 | c.4054G>A p.E1352K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100317576; called by mutect2, varscan2
- CEP350 | c.8677G>C p.E2893Q | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.99); catalogued as COSV62609930; called by muse, mutect2, varscan2
- CEP76 | c.446C>G p.S149C | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV50870789; called by muse, mutect2, varscan2
- CEP95 | c.2117G>C p.R706T | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73609641; called by muse, mutect2, varscan2
- CFAP43 | c.3369G>A p.M1123I | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63855045; called by muse, mutect2, varscan2
- CFTR | c.1693G>C p.D565H | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769476932, COSV50107466, COSV99133859, COSV99139792; called by muse, mutect2, varscan2
- CHI3L2 | c.1050G>C p.K350N | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV63874091, COSV63874411, COSV63874941; called by muse, mutect2, varscan2
- CHST1 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1247517825, COSV57321661; called by muse, mutect2, varscan2
- CHTOP | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV52681225; called by muse, mutect2
- CILK1 | c.1279G>C p.D427H (on ENST00000350082 / NM_001375397.1; = p.D420H on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63154860, COSV63156061; called by muse, mutect2, varscan2
- CLASP1 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV55341405; called by muse, mutect2, varscan2
- CLIP1 | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56800130, COSV56808903; called by muse, mutect2, varscan2
- CNTNAP4 | c.1366G>C p.V456L | Missense Mutation (SNP) | VAF 60/112 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV56677802, COSV56701203; called by muse, mutect2
- COL13A1 | c.503G>C p.R168T (on ENST00000398978 / NM_001130103.2; = p.R130T on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV62575411; called by muse, mutect2, varscan2
- COL2A1 | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.096); catalogued as rs1333696091, COSV61531992, COSV61534702; called by muse, mutect2, varscan2
- COL6A3 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV55111008; called by muse, mutect2, varscan2
- CRACDL | c.2720G>C p.R907T | Missense Mutation (SNP) | VAF 79/216 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67410241; called by muse, mutect2, varscan2
- CRADD | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.303); catalogued as COSV60556713; called by muse, mutect2, varscan2
- CRY1 | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs765830354, COSV50492237; called by muse, mutect2, varscan2
- CSNK2A1 | c.678C>G p.I226M | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV53937815; called by muse, mutect2, varscan2
- CTSF | c.1166-1G>A p.X389_splice | Splice Site (SNP) | VAF 21/48 reads (44%) | catalogued as COSV59750660; called by muse, mutect2, varscan2
- CX3CL1 | c.721C>G p.P241A | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV50056915, COSV50056988; called by muse, mutect2, varscan2
- CX3CL1 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs755935146, COSV50057003; called by muse, varscan2
- CX3CL1 | c.860C>G p.S287C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs542418023, COSV50057018; called by muse, varscan2
- CXCL14 | c.168G>C p.M56I (on ENST00000337225; = p.M44I on NM_004887.5) | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61499563; called by muse, mutect2, varscan2
- CYP2S1 | c.334G>C p.D112H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV59507353; called by muse, mutect2, varscan2
- DBF4 | c.1966G>C p.D656H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV55999143; called by muse, mutect2, varscan2
- DBNL | c.1070C>G p.S357C (on ENST00000448521 / NM_001014436.3; = p.S358C on NM_014063.7) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.662); catalogued as COSV51979793; called by muse, mutect2, varscan2
- DBX1 | c.810G>C p.Q270H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV99910269; called by muse, mutect2, varscan2
- DCC | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as rs112433088, COSV59087894; called by muse, mutect2, varscan2
- DDX46 | c.2841G>C p.W947C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62801130; called by muse, mutect2, varscan2
- DEFB115 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV68723076; called by muse, mutect2, varscan2
- DENND4B | c.3482G>A p.R1161H | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs375041368; called by muse, mutect2, varscan2
- DENND5B | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.388); catalogued as COSV60908648; called by muse, mutect2, varscan2
- DFFA | c.489G>C p.Q163H | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.961); catalogued as COSV65478276; called by muse, mutect2, varscan2
- DIABLO | c.472G>C p.E158Q (on ENST00000443649 / NM_001278303.1; = p.E231Q on NM_019887.6) | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.024); catalogued as COSV57337572; called by muse, mutect2, varscan2
- DNAAF1 | c.2116C>A p.Q706K | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as COSV58989435; called by muse, mutect2, varscan2
- DNAH1 | c.3475G>C p.E1159Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV101326643; called by muse, varscan2
- DNAH7 | c.2002G>C p.E668Q | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV56787554; called by muse, mutect2, varscan2
- DNAH8 | c.1535C>A p.P512H | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59481753; called by muse, mutect2, varscan2
- DNAJC11 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53791123, COSV99602181; called by muse, mutect2
- DNM2 | c.2140G>T p.D714Y (on ENST00000355667 / NM_001005360.3; = p.D710Y on NM_004945.3) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1288607069, COSV53035462; called by muse, mutect2, varscan2
- DNMT3L | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54266162; called by muse, mutect2, varscan2
- DOCK4 | c.4603G>A p.E1535K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV70243401; called by muse, mutect2, varscan2
- DPP4 | c.306C>G p.I102M | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV62109973; called by muse, mutect2, varscan2
- DPY19L2 | c.471C>G p.F157L | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs1363940926, COSV60546079; called by muse, mutect2, varscan2
- DTX3 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.081); catalogued as rs1304375146, COSV54090909; called by muse, mutect2, varscan2
- DTX4 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57095252; called by muse, mutect2, varscan2
- DYNC1H1 | c.8606G>A p.R2869Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as rs776582823, COSV64142826; called by muse, mutect2, varscan2
- DZIP3 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.439); catalogued as COSV64313225; called by muse, mutect2, varscan2
- EMILIN2 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs760175396, COSV54427792; called by muse, mutect2, varscan2
- ENPEP | c.1145C>G p.S382* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV99487073; called by muse, mutect2, varscan2
- EPHA3 | c.594C>G p.Y198* | Nonsense Mutation (SNP) | VAF 44/135 reads (33%) | catalogued as COSV60710674; called by muse, mutect2, varscan2
- EPHB1 | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1369940583, COSV67672154; called by muse, mutect2, varscan2
- EPHX2 | c.807G>T p.E269D | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as COSV100994728; called by muse, mutect2
- ERBB3 | c.2851G>C p.D951H | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57253340, COSV57261713; called by muse, mutect2, varscan2
- ESYT1 | c.2644G>C p.E882Q | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV57276581; called by muse, mutect2, varscan2
- FAM217B | c.21G>A p.W7* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as COSV100674605; called by muse, mutect2, varscan2
- FASN | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100148136; called by muse, mutect2, varscan2
- FAT1 | c.9460G>A p.A3154T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs759492838, COSV101499530; called by muse, mutect2, varscan2
- FAT3 | c.5737G>A p.E1913K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.054); catalogued as COSV99963949, COSV99968656; called by muse, mutect2, varscan2
- FAT4 | c.11410G>C p.D3804H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58709807; called by muse, mutect2
- FBN2 | c.5497T>A p.C1833S | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52546017; called by muse, mutect2, varscan2
- FCRL5 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.414); catalogued as rs1217530344, COSV62520548; called by muse, mutect2, varscan2
- FEZF1 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58659743; called by muse, mutect2, varscan2
- FILIP1 | c.98C>G p.S33* | Nonsense Mutation (SNP) | VAF 18/108 reads (17%) | catalogued as COSV99385685; called by muse, mutect2, varscan2
- FLG | c.4634G>C p.R1545T | Missense Mutation (SNP) | VAF 98/318 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.049); catalogued as rs1348260250, COSV64249840; called by muse, mutect2, varscan2
- FLG | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV100910658, COSV64249847; called by muse, mutect2
- FMNL1 | c.2282A>T p.E761V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58959475; called by muse, mutect2, varscan2
- FN1 | c.6594G>C p.L2198F (on ENST00000359671 / NM_001365524.2; = p.L2167F on NM_002026.4) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV100117804; called by muse, mutect2, varscan2
- FOXP2 | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.87); catalogued as rs764574245, COSV63494273; called by muse, mutect2, varscan2
- FOXRED1 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV55009080; called by muse, mutect2, varscan2
- FUT5 | c.1124G>C p.*375Sext*20 | Nonstop Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as COSV99398901, COSV99398989; called by muse, mutect2, varscan2
- GALK1 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs751610911, COSV56693611, COSV99849300; called by muse, mutect2
- GAPVD1 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV52927647; called by muse, mutect2, varscan2
- GATAD2A | c.375G>C p.L125F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV53076260; called by muse, mutect2, varscan2
- GCSAM | c.211C>G p.P71A | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV58264593; called by muse, mutect2, varscan2
- GJB6 | c.579T>G p.I193M | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as COSV53833615; called by muse, varscan2
- GJB6 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53833623, COSV99575947; called by muse, varscan2
- GNAL | c.453G>C p.E151D (on ENST00000269162 / NM_001142339.3; = p.E228D on NM_182978.4) | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as COSV52334280; called by muse, mutect2, varscan2
- GNPNAT1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as rs749359553, COSV53592475; called by muse, mutect2, varscan2
- GOLM2 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.859); catalogued as rs140660671; called by muse, mutect2, varscan2
- GON4L | c.1888C>G p.L630V | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV99675260; called by muse, mutect2
- GPATCH1 | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV50127157; called by muse, mutect2, varscan2
- GPC2 | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as COSV52786638; called by muse, mutect2, varscan2
- GPR158 | c.2837C>G p.S946* | Nonsense Mutation (SNP) | VAF 55/151 reads (36%) | catalogued as COSV100894089; called by muse, mutect2, varscan2
- GPR161 | c.733T>A p.S245T | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.978); catalogued as COSV54794929; called by muse, mutect2, varscan2
- GPR68 | c.265C>A p.H89N | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as rs1363924937, COSV53177119; called by muse, mutect2, varscan2
- GPS2 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 29/56 reads (52%) | catalogued as rs1455713693, COSV59749746; called by muse, mutect2, varscan2
- GPS2 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV59753334; called by muse, mutect2, varscan2
- GRIA1 | c.1773G>T p.L591F | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as COSV53625434; called by muse, mutect2
- GRIN2C | c.913C>G p.R305G | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV99501275; called by muse, mutect2
- GSDMD | c.798G>T p.M266I | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs1487826353, COSV99369530; called by muse, mutect2, varscan2
- GSS | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs568602749, COSV53628479; called by muse, varscan2
- GTF2I | c.60G>C p.R20S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV60404005; called by muse, mutect2, varscan2
- HADHA | c.1801G>T p.E601* | Nonsense Mutation (SNP) | VAF 127/277 reads (46%) | catalogued as COSV101024093; called by muse, mutect2, varscan2
- HAUS8 | c.371C>A p.S124* | Nonsense Mutation (SNP) | VAF 44/122 reads (36%) | catalogued as COSV99505432, COSV99505488; called by muse, mutect2, varscan2
- HEXIM1 | c.630G>A p.M210I | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); catalogued as COSV60177656; called by muse, mutect2, varscan2
- HIVEP3 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.19); catalogued as COSV56024115; called by muse, mutect2, varscan2
- HLCS | c.1916G>C p.R639T | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60798541; called by muse, mutect2, varscan2
- HMGB2 | c.503G>T p.S168I | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV56634217; called by muse, varscan2
- HNRNPM | c.332C>G p.S111* | Nonsense Mutation (SNP) | VAF 46/153 reads (30%) | catalogued as COSV100335347; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.73); catalogued as COSV100079911, COSV57134093; called by muse, mutect2, varscan2
- HNRNPUL2 | c.745G>C p.D249H | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53666763; called by muse, mutect2, varscan2
- HNRNPUL2 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as rs1429970839, COSV53666768; called by muse, mutect2, varscan2
- IARS2 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs770464072, COSV56964296; called by muse, varscan2
- IARS2 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV56964306; called by muse, varscan2
- IFT172 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV53139679; called by muse, mutect2, varscan2
- IGFN1 | c.1591G>A p.D531N (on ENST00000295591 / NM_001367841.1; = p.D2988N on NM_001164586.2) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.018); catalogued as COSV55185467; called by muse, mutect2, varscan2
- IGHV3-13 | c.79G>C p.G27R | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.783); catalogued as rs112329769; called by muse, mutect2, varscan2
- IGKV2D-29 | c.271G>T p.G91W | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs570525352, COSV72391653; called by muse, mutect2, varscan2
- IGSF9B | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as rs1565425704, COSV58073041; called by muse, varscan2
- IKZF3 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV53107374; called by muse, mutect2, varscan2
- IL4I1 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as rs779468357, COSV62008534, COSV62011091; called by muse, mutect2, varscan2
- ING3 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.885); catalogued as rs753997717, COSV59952229; called by muse, mutect2, varscan2
- IPPK | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99845765; called by muse, mutect2
- IQCJ-SCHIP1 | c.1588G>A p.E530K (on ENST00000485419 / NM_001197113.1; = p.E454K on NM_014575.3) | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61860455; called by muse, mutect2, varscan2
- IQGAP3 | c.845C>A p.A282D | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV63254790; called by muse, mutect2, varscan2
- IRF2BP1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV56195198; called by muse, mutect2, varscan2
- ITGA4 | c.1298C>G p.S433C | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52004416; called by muse, mutect2, varscan2
- ITGA9 | c.268C>G p.H90D | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV53253310; called by muse, mutect2, varscan2
- ITGAM | c.507G>A p.M169I | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54942865; called by muse, mutect2
- ITGB2 | c.2074G>C p.E692Q (on ENST00000302347; = p.E668Q on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV56614224; called by muse, mutect2, varscan2
- ITIH2 | c.978G>T p.M326I | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.998); catalogued as COSV64432975, COSV64435333; called by muse, mutect2, varscan2
- ITPR2 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1234767915, COSV67276441; called by muse, mutect2, varscan2
- JAG1 | c.2000-1G>A p.X667_splice | Splice Site (SNP) | VAF 13/56 reads (23%) | catalogued as COSV54763177; called by muse, mutect2, varscan2
- KANSL3 | c.779T>A p.L260H | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV62623318; called by muse, mutect2, varscan2
- KCNJ16 | c.552C>G p.F184L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52252283, COSV52255295, COSV52257518; called by muse, mutect2, varscan2
- KCNJ6 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.966); catalogued as COSV55723610; called by muse, mutect2, varscan2
- KDM2B | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.491); catalogued as rs782101520, COSV65640692; called by muse, mutect2, varscan2
- KMT2B | c.5612C>T p.S1871L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs1432547195, COSV55861922; called by muse, mutect2, varscan2
- KMT2D | c.13039C>T p.Q4347* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV56447684, COSV99980116; called by muse, mutect2, varscan2
- KRT26 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV59415827; called by muse, mutect2, varscan2
- KRT38 | c.667G>T p.D223Y | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55847630, COSV55847725; called by muse, mutect2, varscan2
- LATS1 | c.2257G>C p.E753Q | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53586481, COSV53590554; called by muse, mutect2, varscan2
- LCMT2 | c.1948G>C p.E650Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV59791515; called by muse, mutect2, varscan2
- LEFTY2 | c.668C>G p.S223W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as COSV100832629; called by muse, mutect2
- LMO7 | c.977G>A p.R326K (on ENST00000357063; = p.R341K on NM_005358.5) | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV58549575; called by muse, mutect2, varscan2
- LRBA | c.1535C>G p.S512* | Nonsense Mutation (SNP) | VAF 33/125 reads (26%) | catalogued as COSV100841954, COSV63955869; called by muse, mutect2, varscan2
- LRIF1 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV100870878, COSV63898488; called by muse, mutect2, varscan2
- LRIG3 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 76/194 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.304); catalogued as rs915896402, COSV57870204; called by muse, mutect2, varscan2
- LRP2 | c.4600G>T p.E1534* | Nonsense Mutation (SNP) | VAF 15/91 reads (16%) | catalogued as COSV99789681; called by muse, mutect2, varscan2
- LRP5 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs764331609, COSV53723991; called by muse, mutect2, varscan2
- LRRIQ1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV67813625; called by muse, mutect2, varscan2
- MACF1 | c.21232G>C p.E7078Q (on ENST00000372915; = p.E5123Q on NM_012090.5) | Missense Mutation (SNP) | VAF 62/188 reads (33%) | catalogued as COSV57145129; called by muse, mutect2, varscan2
- MAGEE1 | c.2768G>A p.R923K | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as COSV63912191; called by muse, mutect2, varscan2
- MAP1B | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as COSV57095914; called by muse, mutect2, varscan2
- MAP3K5 | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs1330127225, COSV62892397; called by muse, mutect2, varscan2
- MAP4K4 | c.3394G>C p.E1132Q (on ENST00000347699 / NM_001242559.2; = p.E1058Q on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); catalogued as COSV56340879; called by muse, mutect2, varscan2
- MAU2 | c.1356C>T p.V452= | Splice Region (SNP) | VAF 24/103 reads (23%) | catalogued as COSV53238332; called by muse, mutect2, varscan2
- MCCC1 | c.1154G>C p.R385T | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55611995; called by muse, mutect2
- MCCC2 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV60157042; called by muse, mutect2, varscan2
- MED13 | c.4468C>T p.P1490S | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs756580776, COSV67267234; called by muse, mutect2, varscan2
- METTL18 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as COSV53682894; called by muse, mutect2, varscan2
- METTL3 | c.948C>G p.F316L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV52971432; called by muse, mutect2, varscan2
- MGAT5B | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV56937195; called by muse, mutect2, varscan2
- MGST1 | c.424C>G p.L142V | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV50567583; called by muse, mutect2, varscan2
- MGST2 | c.52C>G p.Q18E | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.801); catalogued as COSV55498721; called by muse, varscan2
- MIPEP | c.450G>C p.E150D | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1284119770, COSV66301999; called by muse, mutect2, varscan2
- MKRN3 | c.843G>C p.Q281H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV58812309; called by muse, mutect2, varscan2
- MPDZ | c.863G>C p.G288A | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59954414; called by muse, mutect2, varscan2
- MROH6 | c.1651G>C p.E551Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV99074129, COSV99074130; called by muse, mutect2
- MRPL24 | c.8T>C p.L3P | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61978058; called by muse, mutect2, varscan2
- MS4A14 | c.1961G>A p.W654* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as rs368014397; called by muse, mutect2, varscan2
- MSI2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52357211, COSV52367499; called by muse, mutect2, varscan2
- MST1 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV56531877; called by muse, mutect2, varscan2
- MYBL1 | c.1195C>G p.Q399E | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.449); catalogued as COSV72919235; called by muse, mutect2, varscan2
- MYBL1 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV101576587; called by muse, mutect2, varscan2
- MYH15 | c.5593C>G p.Q1865E | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56308123; called by muse, mutect2, varscan2
- MYO10 | c.1744G>C p.D582H | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72563648; called by muse, mutect2, varscan2
- MYO1B | c.1600C>G p.L534V | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as COSV58438241; called by muse, mutect2, varscan2
- MYO1G | c.1272C>G p.I424M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51857153; called by muse, mutect2, varscan2
- MYO5B | c.2180C>G p.S727C | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.322); catalogued as COSV53231593; called by muse, mutect2, varscan2
- NDUFAF7 | c.1255C>G p.Q419E | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV50018969; called by muse, mutect2, varscan2
- NEB | c.18838G>C p.E6280Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV50892431, COSV99425951; called by muse, mutect2, varscan2
- NEK6 | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.039); catalogued as rs1376354948, COSV57221475; called by muse, mutect2, varscan2
- NGLY1 | c.354G>C p.K118N | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs752256415, COSV54991647; called by muse, mutect2, varscan2
- NHS | c.2999C>T p.P1000L | Missense Mutation (SNP) | VAF 45/71 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66282947; called by muse, mutect2, varscan2
- NIPSNAP3B | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150554330; called by muse, mutect2, varscan2
- NKTR | c.1900C>T p.Q634* | Nonsense Mutation (SNP) | VAF 45/139 reads (32%) | catalogued as COSV99236116; called by muse, mutect2, varscan2
- NLGN2 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV57211465, COSV57212358; called by muse, mutect2, varscan2
- NLRP13 | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.397); catalogued as COSV61620373; called by muse, mutect2, varscan2
- NPEPPS | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV59105779; called by muse, mutect2, varscan2
- NPY | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54216077; called by muse, mutect2
- NRCAM | c.343G>C p.E115Q (on ENST00000379028 / NM_001371124.1; = p.E109Q on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV61049576; called by muse, mutect2, varscan2
- NSD2 | c.2333C>G p.S778* | Nonsense Mutation (SNP) | VAF 40/114 reads (35%) | catalogued as COSV100373676; called by muse, mutect2, varscan2
- NSG1 | c.132G>C p.V44= | Splice Region (SNP) | VAF 10/44 reads (23%) | catalogued as COSV67575770; called by muse, mutect2, varscan2
- NTPCR | c.131G>C p.G44A | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.292); catalogued as COSV64053065; called by muse, mutect2, varscan2
- NUP155 | c.1762C>G p.L588V (on ENST00000231498 / NM_153485.3; = p.L529V on NM_004298.4) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV51534927; called by muse, mutect2, varscan2
- NUP188 | c.4549C>T p.R1517* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as rs1319531334, COSV100999366; called by muse, mutect2, varscan2
- OAS1 | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.035); catalogued as COSV52538308, COSV52538914; called by muse, mutect2, varscan2
- OGDH | c.1786G>C p.D596H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV56057327; called by muse, mutect2, varscan2
- OGDH | c.2091G>C p.K697N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as COSV56051820; called by muse, mutect2, varscan2
- OR10Z1 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.919); catalogued as COSV63526575; called by muse, mutect2, varscan2
- OR2D2 | c.684G>A p.M228I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV55058311; called by muse, mutect2, varscan2
- OR2F2 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 74/245 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68833411; called by muse, mutect2, varscan2
- OR2V2 | c.68C>T p.T23I | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs756871080, COSV60316576; called by muse, mutect2, varscan2
- OR2W1 | c.915G>A p.M305I | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1373782305, COSV65851947; called by muse, mutect2, varscan2
- PABPC3 | c.856G>C p.D286H | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV55806728; called by muse, varscan2
- PABPN1L | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1354568146, COSV56352885; called by muse, mutect2, varscan2
- PACSIN3 | c.1165G>T p.E389* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100096509; called by muse, mutect2, varscan2
- PAXIP1 | c.2884G>A p.E962K | Missense Mutation (SNP) | VAF 80/194 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as COSV66898963; called by muse, mutect2, varscan2
- PCBP1 | c.1029C>G p.I343M | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57851986; called by muse, mutect2, varscan2
- PCDHGA3 | c.1117G>C p.D373H | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54037592; called by muse, mutect2, varscan2
- PCDHGA3 | c.1283G>T p.G428V | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53972237, COSV54018156; called by muse, mutect2, varscan2
- PCIF1 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs140304055, COSV59820394; called by muse, mutect2, varscan2
- PDXK | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV99376612; called by muse, mutect2, varscan2
- PFKP | c.1911A>G p.R637= | Splice Region (SNP) | VAF 15/168 reads (9%) | catalogued as COSV56540154; called by muse, mutect2
- PHLDB2 | c.2572G>A p.D858N (on ENST00000393925 / NM_001134439.2; = p.D815N on NM_145753.2) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as COSV67309477, COSV67316332; called by muse, mutect2, varscan2
- PIK3R4 | c.1275C>G p.F425L | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63243993; called by muse, mutect2, varscan2
- PIWIL2 | c.1500G>A p.M500I | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV63254156; called by muse, mutect2, varscan2
- PKDCC | c.1008G>C p.E336D | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.835); catalogued as COSV99684936; called by muse, mutect2
- PLCB1 | c.3343G>A p.E1115K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as COSV62069422; called by muse, mutect2, varscan2
- PLEKHM3 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as COSV66818842; called by muse, mutect2, varscan2
- PLIN2 | c.901C>G p.H301D | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.6); PolyPhen benign (0.338); catalogued as COSV52804487; called by muse, mutect2, varscan2
- POLR1B | c.1804_1805insC p.G602Afs*17 | Frame Shift Ins (INS) | VAF 18/87 reads (21%) | catalogued as COSV54503872; called by mutect2, pindel*, varscan2
- PPFIA1 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 69/346 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs747220973, COSV54140972; called by muse, mutect2, varscan2
- PPFIA4 | c.3419C>T p.S1140F (on ENST00000447715; = p.S1141F on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs750383750, COSV55323024; called by muse, varscan2
- PPL | c.2472G>C p.K824N | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs990533110, COSV62051156; called by muse, mutect2, varscan2
- PPP2R1B | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV100231991, COSV59537753; called by muse, mutect2, varscan2
- PPP2R2C | c.683C>G p.S228C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV58676753; called by muse, mutect2, varscan2
- PPP4R3B | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV55402406, COSV55409407; called by muse, mutect2, varscan2
- PRAMEF4 | c.1078G>T p.D360Y | Missense Mutation (SNP) | VAF 88/299 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV52441512; called by muse, mutect2, varscan2
- PRKAB1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.311); catalogued as COSV57554979; called by muse, mutect2, varscan2
- PRKCQ | c.1179+2T>A p.X393_splice | Splice Site (SNP) | VAF 55/165 reads (33%) | catalogued as COSV54119516; called by muse, mutect2, varscan2
- PRPF8 | c.2800C>T p.R934C | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs758120082, COSV59268017; called by muse, mutect2
- RASA1 | c.2571G>C p.E857D | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV57202219, COSV57202499; called by muse, mutect2, varscan2
- RASAL2 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62723917; called by muse, mutect2, varscan2
- RBBP6 | c.4270C>T p.Q1424* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as COSV100154817; called by muse, mutect2, varscan2
- RBL2 | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV50889174; called by muse, mutect2, varscan2
- RBM5 | c.1441G>T p.D481Y | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61739127; called by muse, mutect2, varscan2
- RC3H1 | c.1377G>C p.L459F | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.759); catalogued as COSV51218038; called by muse, mutect2
- RDH12 | c.896C>G p.T299R | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV50823208; called by muse, mutect2, varscan2
- REG1B | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV59305199; called by muse, mutect2, varscan2
- RLIM | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.15); PolyPhen benign (0.196); catalogued as COSV60329276; called by muse, mutect2, varscan2
- RNF123 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV59684295, COSV59692682; called by muse, mutect2, varscan2
- RNF180 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV56965367; called by muse, mutect2, varscan2
- RNF7 | c.59C>G p.S20* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as COSV99857952; called by muse, mutect2, varscan2
- RORB | c.127G>A p.G43R (on ENST00000396204 / NM_001365023.1; = p.G32R on NM_006914.4) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65337647; called by muse, mutect2, varscan2
- RPL7L1 | c.188C>A p.S63* | Nonsense Mutation (SNP) | VAF 20/78 reads (26%) | catalogued as rs1273917912, COSV100491777; called by muse, mutect2, varscan2
- RPL8 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1157704484, COSV52800161; called by muse, mutect2, varscan2
- RPRD2 | c.1665A>T p.E555D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.584); catalogued as COSV64821791; called by muse, mutect2, varscan2
- RPS6KA5 | c.1261C>G p.Q421E | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV56225919; called by muse, mutect2, varscan2
- RRAGD | c.760-1G>C p.X254_splice | Splice Site (SNP) | VAF 44/123 reads (36%) | catalogued as COSV100784614, COSV63270305; called by muse, mutect2, varscan2
- RRBP1 | c.4071G>C p.K1357N (on ENST00000377813 / NM_001365613.2; = p.K924N on NM_004587.3) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55709158; called by muse, mutect2, varscan2
- RTL3 | c.1358A>T p.H453L | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV58185958; called by muse, mutect2, varscan2
- SAMD9L | c.1031G>C p.R344T | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59085478; called by muse, mutect2
- SATB1 | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV58672906; called by muse, mutect2, varscan2
- SCAP | c.1710dup p.S571Qfs*13 | Frame Shift Ins (INS) | VAF 12/44 reads (27%) | catalogued as rs1229536681; called by mutect2, pindel, varscan2
- SCLT1 | c.603G>C p.E201D | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV55413047; called by muse, mutect2, varscan2
- SCNN1B | c.1491C>G p.I497M | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV56310379; called by muse, mutect2, varscan2
- SCUBE2 | c.2949C>G p.I983M (on ENST00000649792 / NM_001367977.2; = p.I926M on NM_020974.3) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV58546959; called by muse, mutect2, varscan2
- SEC63 | c.1771G>T p.D591Y | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV64602248; called by muse, mutect2, varscan2
- SEL1L2 | c.230T>G p.I77R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV53158555; called by muse, mutect2, varscan2
- SENP7 | c.365C>G p.A122G | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV58619915; called by muse, mutect2
- SETD9 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.397); catalogued as COSV53651247; called by muse, mutect2, varscan2
- SETD9 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV53650543, COSV53651267; called by muse, mutect2, varscan2
- SETX | c.4726G>A p.E1576K | Missense Mutation (SNP) | VAF 59/96 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV56395101; called by muse, mutect2, varscan2
- SGK3 | c.337G>T p.V113F | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.316); catalogued as COSV61897056; called by muse, mutect2, varscan2
- SH2B3 | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1412875800, COSV57986814; called by muse, mutect2, varscan2
- SH3D19 | c.381G>C p.E127D | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV58794424; called by muse, mutect2, varscan2
- SIM2 | c.702C>G p.F234L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs374786343, COSV51768644; called by muse, mutect2, varscan2
- SIPA1L1 | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs879190236, COSV62173845; called by muse, mutect2, varscan2
- SIX3 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs746508020, COSV53228731; called by muse, mutect2, varscan2
- SLAIN1 | c.701G>T p.G234V (on ENST00000466548; = p.G92V on NM_001040153.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV57387319; called by muse, mutect2, varscan2
- SLC12A8 | c.2049G>A p.M683I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV100102914; called by muse, mutect2, varscan2
- SLC12A8 | c.1748G>A p.R583K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV100102279, COSV58871134; called by muse, mutect2, varscan2
- SLC22A14 | c.621G>A p.K207= | Splice Region (SNP) | VAF 26/69 reads (38%) | catalogued as COSV56199518; called by muse, mutect2, varscan2
- SLC25A24 | c.686C>G p.S229* | Nonsense Mutation (SNP) | VAF 19/30 reads (63%) | catalogued as COSV51450206, COSV51451088; called by muse, mutect2, varscan2
- SLC26A7 | c.306C>T p.G102= | Splice Region (SNP) | VAF 19/86 reads (22%) | catalogued as rs1212339226, COSV52591193; called by muse, mutect2, varscan2
- SLC2A10 | c.666C>G p.F222L | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as COSV63714590, COSV63716066; called by muse, mutect2, varscan2
- SLC39A10 | c.968del p.S323Ffs*2 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | catalogued as COSV62768446, COSV62769006, COSV62769687; called by mutect2, pindel, varscan2
- SLC49A4 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.037); catalogued as COSV53749501, COSV99658790; called by muse, mutect2, varscan2
- SLC9A2 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 52/214 reads (24%) | catalogued as COSV99296589; called by muse, mutect2, varscan2
- SMC5 | c.1277G>C p.R426T | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV63195675, COSV99082085; called by muse, mutect2, varscan2
- SNRPA1 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs772297229, COSV54258497; called by muse, mutect2, varscan2
- SOAT2 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56860938; called by muse, mutect2, varscan2
- SP2 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 22/77 reads (29%) | catalogued as rs1268682179, COSV100947267; called by muse, varscan2
- SP4 | c.2115G>C p.K705N | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56023696; called by muse, mutect2, varscan2
- SPATA45 | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60572784; called by muse, mutect2
- SRRT | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100730292; called by muse, mutect2, varscan2
- STAB2 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV101186010, COSV66347467; called by muse, mutect2, varscan2
- STAT4 | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs376947712; called by muse, mutect2, varscan2
- STK24 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756164380, COSV64823825; called by muse, mutect2, varscan2
- STK38 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV57710806; called by muse, mutect2, varscan2
- STRADB | c.316-1G>C p.X106_splice | Splice Site (SNP) | VAF 21/89 reads (24%) | catalogued as COSV52045949; called by muse, mutect2
- SUPT20H | c.793G>C p.D265H (on ENST00000350612 / NM_001014286.3; = p.D266H on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV62249804; called by muse, mutect2, varscan2
- SUPT5H | c.1486G>C p.E496Q | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63242277; called by muse, mutect2, varscan2
- SYNE2 | c.4168G>C p.D1390H | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); catalogued as rs748204670, COSV59960346, COSV59971077; called by muse, mutect2, varscan2
- SYNM | c.1854C>G p.F618L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV60375114; called by muse, mutect2, varscan2
- TAF4B | c.1432G>T p.A478S | Missense Mutation (SNP) | VAF 84/177 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV52310373; called by muse, mutect2, varscan2
- TANC1 | c.3497C>G p.S1166* | Nonsense Mutation (SNP) | VAF 21/66 reads (32%) | catalogued as COSV99714721; called by muse, mutect2, varscan2
- TANC2 | c.2079G>T p.M693I | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV67341921; called by muse, mutect2, varscan2
- TARS1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.037); catalogued as COSV54312504; called by muse, mutect2, varscan2
- TAZ | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 152/208 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV54797457; called by muse, varscan2
- TBC1D16 | c.1439T>G p.F480C | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV60481490; called by muse, mutect2
- TBC1D2B | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV56040000; called by muse, mutect2, varscan2
- TBX5 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as CM971436, COSV59858590; called by muse, mutect2, varscan2
- TCF25 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs772100257, COSV54533255; called by muse, varscan2
- TCTN2 | c.623G>C p.G208A | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV57635121; called by muse, mutect2, varscan2
- TEX14 | c.1234C>G p.R412G (on ENST00000240361 / NM_001201457.2; = p.R406G on NM_031272.5) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs753803044, COSV53626935; called by muse, mutect2, varscan2
- THEM5 | c.495G>T p.M165I | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV64313257; called by muse, mutect2, varscan2
- THSD7B | c.4417C>G p.R1473G (on ENST00000272643; = p.R1471G on NM_001316349.2) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as rs368781810, COSV99755798; called by muse, mutect2, varscan2
- THUMPD3 | c.936C>G p.L312= | Splice Region (SNP) | VAF 36/172 reads (21%) | catalogued as COSV61506846; called by muse, mutect2, varscan2
- TIGD5 | c.1385G>C p.G462A | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV99643600; called by muse, mutect2
- TLK1 | c.978G>A p.V326= | Splice Region (SNP) | VAF 14/66 reads (21%) | catalogued as COSV62633232; called by muse, mutect2, varscan2
- TLR1 | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV58303096, COSV58303484; called by muse, mutect2, varscan2
- TLR8 | c.1348C>G p.H450D (on ENST00000218032 / NM_138636.5; = p.H468D on NM_016610.4) | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.621); catalogued as COSV54320832; called by muse, mutect2, varscan2
- TM6SF1 | c.355C>G p.H119D | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51946630, COSV99362696; called by muse, mutect2, varscan2
- TMCC3 | c.664C>T p.H222Y | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1338119943, COSV54157834; called by muse, mutect2, varscan2
- TMED6 | c.89C>G p.S30C | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV54749129; called by muse, mutect2, varscan2
- TMEM135 | c.869C>G p.S290C | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV59706874; called by muse, mutect2
- TMEM175 | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV53281357; called by muse, varscan2
- TMEM181 | c.252G>C p.Q84H | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.264); catalogued as COSV65565991; called by muse, mutect2, varscan2
- TMEM94 | c.2161G>C p.D721H | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58596577; called by muse, mutect2, varscan2
- TMPPE | c.1188G>T p.Q396H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.433); catalogued as COSV56568187; called by muse, mutect2, varscan2
- TMPRSS6 | c.481G>T p.V161L | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV60984093; called by muse, mutect2, varscan2
- TNFRSF21 | c.915C>A p.H305Q | Missense Mutation (SNP) | VAF 51/250 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.047); catalogued as rs1372040314, COSV57285260; called by muse, mutect2, varscan2
- TNFSF13 | c.14C>G p.S5C | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV53434157; called by muse, mutect2, varscan2
- TNPO3 | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.215); catalogued as COSV55287127; called by muse, mutect2, varscan2
- TNS3 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747272053, COSV60798061; called by muse, mutect2, varscan2
- TOB1 | c.136C>A p.P46T | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV52149817, COSV52150910, COSV52151007; called by muse, mutect2, varscan2
- TP53BP2 | c.2242G>A p.E748K (on ENST00000343537 / NM_001031685.3; = p.E619K on NM_005426.2) | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs1165741377, COSV59073254; called by muse, mutect2, varscan2
- TPD52 | c.419C>G p.S140C (on ENST00000379097 / NM_001025252.3; = p.S100C on NM_005079.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV66951953; called by muse, mutect2, varscan2
- TRAK2 | c.1740C>A p.N580K | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV60275364; called by muse, mutect2, varscan2
- TRAPPC6A | c.53T>A p.L18Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50065567; called by muse, mutect2, varscan2
- TRIM11 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.068); catalogued as rs1464481144, COSV52860254; called by muse, mutect2, varscan2
- TRIM71 | c.847G>C p.D283H | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.737); catalogued as COSV67472798; called by muse, mutect2, varscan2
- TRPC1 | c.673C>G p.L225V (on ENST00000476941 / NM_001251845.2; = p.L191V on NM_003304.4) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1225925790, COSV56430331; called by muse, mutect2, varscan2
- TRPM8 | c.2471C>G p.S824C | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV61224377; called by muse, mutect2, varscan2
- TRPS1 | c.453G>T p.K151N (on ENST00000220888 / NM_001330599.2; = p.K164N on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV55249279; called by muse, mutect2, varscan2
- TSEN34 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | catalogued as COSV99824963; called by muse, mutect2, varscan2
- TSPAN3 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 40/94 reads (43%) | catalogued as COSV99144459; called by muse, mutect2, varscan2
- TTBK2 | c.2524G>T p.E842* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV99142190, COSV99142552; called by muse, varscan2
- TTBK2 | c.2470G>C p.D824H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV51180297; called by muse, varscan2
- TTC3 | c.5453G>A p.R1818Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs925994691, COSV61291026, COSV61296487; called by muse, mutect2, varscan2
- TTC7A | c.2192G>C p.G731A | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV55415614; called by muse, mutect2, varscan2
- TTN | c.13675G>A p.D4559N (on ENST00000591111; = p.D3632N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | PolyPhen possibly damaging (0.876); catalogued as COSV60180688, COSV60360996; called by muse, mutect2, varscan2
- TTN | c.12389C>T p.S4130L (on ENST00000591111; = p.S4084L on NM_003319.4) | Missense Mutation (SNP) | VAF 28/109 reads (26%) | catalogued as rs777547090, COSV60033164; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- UACA | c.4195G>C p.D1399H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59860193; called by muse, mutect2, varscan2
- UBE2Q2 | c.568C>G p.Q190E | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV51196923; called by muse, mutect2, varscan2
- UBE4A | c.1089C>G p.I363M (on ENST00000252108 / NM_001204077.2; = p.I370M on NM_004788.4) | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.453); catalogued as rs769625932, COSV52807010; called by muse, varscan2
- UBE4A | c.1292C>G p.S431* (on ENST00000252108 / NM_001204077.2; = p.S438* on NM_004788.4) | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV99348447; called by muse, varscan2
- UGT2A1 | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54146732; called by muse, mutect2, varscan2
- UNC79 | c.3062C>G p.S1021C (on ENST00000393151 / NM_001346218.2; = p.S844C on NM_020818.5) | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV56373170, COSV56412161; called by muse, mutect2, varscan2
- UQCR10 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as rs374152934, COSV57458811; called by muse, mutect2, varscan2
- USF3 | c.3439G>C p.E1147Q | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.92); catalogued as COSV57073379, COSV57077648; called by muse, mutect2, varscan2
- USP43 | c.2443C>G p.L815V | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV53307166; called by muse, mutect2, varscan2
- USP43 | c.3277C>T p.P1093S | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV53300203; called by muse, mutect2, varscan2
- USP53 | c.2225C>G p.S742C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.818); catalogued as COSV56797838; called by muse, mutect2, varscan2
- USP9Y | c.6586C>A p.Q2196K | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV59100677; called by muse, mutect2, varscan2
- UTP11 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 20/92 reads (22%) | catalogued as COSV100884970; called by muse, mutect2, varscan2
- UTRN | c.1762G>T p.D588Y | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV62348509; called by muse, mutect2, varscan2
- VPS13C | c.9370A>G p.K3124E (on ENST00000644861 / NM_020821.3; = p.K3081E on NM_017684.5) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV51425924; called by muse, mutect2, varscan2
- WAC | c.1273C>T p.Q425* | Nonsense Mutation (SNP) | VAF 34/128 reads (27%) | catalogued as COSV61566797; called by muse, mutect2, varscan2
- WAC | c.1375C>T p.Q459* | Nonsense Mutation (SNP) | VAF 36/120 reads (30%) | catalogued as COSV61567752, COSV61570303; called by muse, mutect2, varscan2
- XIRP1 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV61138455; called by muse, mutect2, varscan2
- XRCC2 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as COSV100831667; called by muse, mutect2, varscan2
- XRCC4 | c.816G>C p.R272S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1461380127, COSV56546193; called by muse, mutect2, varscan2
- ZBTB21 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60405919; called by muse, mutect2, varscan2
- ZBTB38 | c.2021C>G p.S674* | Nonsense Mutation (SNP) | VAF 28/82 reads (34%) | catalogued as COSV100375883; called by muse, mutect2, varscan2
- ZNF333 | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV52887572; called by muse, mutect2, varscan2
- ZNF429 | c.1495C>T p.H499Y | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61919248; called by muse, mutect2, varscan2
- ZNF530 | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs377140495; called by muse, mutect2, varscan2
- ZNF551 | c.1731C>A p.H577Q | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1334451171, COSV56595236; called by muse, mutect2, varscan2
- ZNF699 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs781646738, COSV58027108; called by muse, mutect2, varscan2
- ZNF791 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.78); catalogued as rs1159956844, COSV58482912; called by muse, mutect2, varscan2
- ZNFX1 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV65579444; called by muse, mutect2, varscan2
- ZSWIM1 | c.457C>G p.P153A | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV54851745; called by muse, mutect2, varscan2
- ZYG11B | c.1381G>T p.D461Y | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV53757371, COSV99596674; called by muse, mutect2, varscan2
- ZZEF1 | c.7813G>C p.D2605H | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV67560336; called by muse, mutect2, varscan2
- CCR5 | c.570G>A p.W190* | Nonsense Mutation (SNP) | VAF 109/346 reads (32%) | called by muse, varscan2
- ESRP2 | c.1818del p.S607Lfs*29 (on ENST00000565858 / NM_001365264.1; = p.S597Lfs*29 on NM_024939.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by mutect2, pindel, varscan2
- FBXO5 | c.620del p.K207Rfs*9 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.913C>T p.H305Y | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.74); PolyPhen benign (0.14); called by muse, varscan2
- KNL1 | c.3064_3065del p.S1022Cfs*8 (on ENST00000346991 / NM_170589.5; = p.S996Cfs*8 on NM_144508.5) | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by pindel, varscan2
- PLXNB2 | c.4931_4944del p.L1644Rfs*25 | Frame Shift Del (DEL) | VAF 18/32 reads (56%) | called by mutect2, varscan2
- PRAMEF17 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- PSMD8 | c.189G>C p.K63N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by mutect2, varscan2
- SMC1A | c.2110C>G p.Q704E | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- SRD5A3 | c.415C>G p.H139D | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- TADA2A | c.1305C>G p.I435M | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- TAF15 | c.1132C>T p.Q378* (on ENST00000605844 / NM_139215.3; = p.Q375* on NM_003487.4) | Nonsense Mutation (SNP) | VAF 29/101 reads (29%) | called by muse, mutect2, varscan2
- ABCC1 | c.3282C>T p.F1094= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV60685924; called by muse, mutect2, varscan2
- ACE | c.3156G>A p.L1052= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV52013384; called by muse, mutect2, varscan2
- ACTC1 | c.468C>T p.D156= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV51761677; called by muse, mutect2, varscan2
- ADPRH | c.753G>T p.V251= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV63695783; called by muse, mutect2, varscan2
- ALAS1 | c.1380G>C p.L460= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV59627075, COSV59629784; called by muse, mutect2, varscan2
- ARHGAP30 | c.2947C>A p.R983= (on ENST00000368013 / NM_001025598.2; = p.R772= on NM_181720.3) | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV63519651; called by muse, mutect2, varscan2
- ARID2 | c.3369G>T p.G1123= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV57614945; called by muse, mutect2, varscan2
- ARMC9 | c.1512C>T p.L504= | Silent (SNP) | VAF 52/104 reads (50%) | catalogued as rs774976384, COSV63023848; called by muse, mutect2, varscan2
- ATP13A5 | c.1617C>G p.L539= | Silent (SNP) | VAF 49/101 reads (49%) | catalogued as COSV60875769; called by muse, mutect2, varscan2
- BRCA2 | c.9153A>C p.P3051= | Silent (SNP) | VAF 8/120 reads (7%) | catalogued as COSV66462661; called by muse, mutect2
- C16orf89 | c.177G>A p.L59= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV60126652; called by muse, mutect2, varscan2
- C3AR1 | c.534C>T p.L178= | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as COSV50825226; called by muse, mutect2, varscan2
- CACNA1E | c.3408C>T p.F1136= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV62426110; called by muse, mutect2, varscan2
- CACNG2 | c.498G>A p.K166= | Silent (SNP) | VAF 80/160 reads (50%) | catalogued as rs911651890, COSV55641295; called by muse, varscan2
- CACNG4 | c.450C>A p.L150= | Silent (SNP) | VAF 52/144 reads (36%) | catalogued as COSV50928115; called by muse, mutect2, varscan2
- CARD9 | c.1044G>A p.L348= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV100261334; called by muse, mutect2
- CASP2 | c.318G>A p.L106= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV60083311; called by muse, mutect2, varscan2
- CCDC62 | c.1647C>T p.L549= | Silent (SNP) | VAF 88/256 reads (34%) | catalogued as COSV53437139; called by muse, mutect2, varscan2
- CCDC96 | c.942G>A p.R314= | Silent (SNP) | VAF 46/135 reads (34%) | catalogued as rs1368428376, COSV59509616; called by muse, mutect2, varscan2
- CCNH | c.879G>A p.K293= | Silent (SNP) | VAF 68/131 reads (52%) | catalogued as COSV56926329; called by muse, mutect2, varscan2
- CDK5 | c.264G>A p.K88= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs1329608831, COSV52525964; called by muse, mutect2, varscan2
- CDK5 | c.105G>A p.V35= | Silent (SNP) | VAF 66/213 reads (31%) | catalogued as COSV52525971; called by muse, mutect2, varscan2
- CEP68 | c.1254G>A p.L418= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as rs752630437, COSV53127700; called by muse, mutect2, varscan2
- CFAP69 | c.2778G>A p.V926= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV60188621; called by muse, mutect2, varscan2
- CNGB3 | c.1944G>A p.Q648= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs1415504913, COSV60698795; called by muse, mutect2, varscan2
- COL20A1 | c.1155G>C p.L385= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100491056; called by muse, varscan2
- COL7A1 | c.5715C>T p.V1905= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs984384543, COSV100097122; called by muse, mutect2, varscan2
- COL7A1 | c.549G>A p.L183= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV60403431; called by muse, mutect2, varscan2
- CPSF1 | c.1263G>A p.K421= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV62942509; called by muse, mutect2, varscan2
- CTTN | c.174G>C p.L58= | Silent (SNP) | VAF 57/206 reads (28%) | catalogued as COSV57236398; called by muse, mutect2, varscan2
- CXXC4 | c.651C>T p.L217= | Silent (SNP) | VAF 70/210 reads (33%) | catalogued as rs753949637, COSV67295948, COSV67296991; called by muse, mutect2, varscan2
- CYP3A43 | c.285G>A p.V95= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV55938165; called by muse, mutect2, varscan2
- DDX5 | c.1704G>A p.Q568= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as rs1008365318, COSV56751449; called by muse, mutect2, varscan2
- DECR1 | c.705C>T p.F235= | Silent (SNP) | VAF 46/141 reads (33%) | catalogued as COSV55170804; called by muse, mutect2, varscan2
- DLG5 | c.1380C>G p.L460= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV64950088; called by muse, mutect2, varscan2
- DMD | c.8382C>G p.L2794= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV58955145; called by muse, mutect2, varscan2
- DNAI1 | c.1962C>T p.I654= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV54284929; called by muse, mutect2, varscan2
- DSTYK | c.1551C>T p.L517= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100904666; called by muse, mutect2
- DUOX1 | c.3708C>A p.I1236= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as COSV58486669; called by muse, mutect2, varscan2
- DUSP7 | c.894C>T p.I298= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV56589763; called by muse, mutect2, varscan2
- DYNC2H1 | c.8742G>A p.L2914= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1231435584, COSV62107320; called by muse, mutect2, varscan2
- EFTUD2 | c.1491G>C p.L497= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs773485121, COSV68184918; called by muse, mutect2, varscan2
- ENG | c.204C>T p.F68= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as COSV61229054; called by muse, mutect2, varscan2
- ENTPD1 | c.1374G>A p.L458= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV64604487; called by muse, mutect2, varscan2
- ENTPD3 | c.1203G>A p.Q401= | Silent (SNP) | VAF 40/148 reads (27%) | catalogued as COSV57196481; called by muse, varscan2
- EZH1 | c.417G>C p.V139= | Silent (SNP) | VAF 48/110 reads (44%) | catalogued as COSV70550815; called by muse, mutect2, varscan2
- FAAP100 | c.1449G>T p.L483= | Silent (SNP) | VAF 34/134 reads (25%) | catalogued as COSV59887766; called by muse, mutect2, varscan2
- FAHD2B | c.649C>T p.L217= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99738188; called by muse, mutect2, varscan2
- FBXO42 | c.1233G>A p.L411= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV65047035; called by muse, mutect2, varscan2
- FCGBP | c.7995C>G p.L2665= | Silent (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- FCGBP | c.4392C>G p.L1464= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV55455638; called by muse, mutect2, varscan2
- FOCAD | c.2085C>G p.L695= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV58107918; called by muse, mutect2, varscan2
- FOXJ1 | c.294G>A p.R98= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs1283026774, COSV53948520, COSV99487316; called by muse, mutect2, varscan2
- FOXQ1 | c.381C>G p.L127= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV57259461; called by muse, mutect2, varscan2
- FOXQ1 | c.624C>G p.V208= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs969843697, COSV99723324; called by muse, mutect2
- FSTL5 | c.828G>C p.L276= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV60231834; called by muse, mutect2, varscan2
- GFOD1 | c.78C>T p.F26= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV64953408; called by muse, mutect2, varscan2
- GPN1 | c.762C>G p.L254= | Silent (SNP) | VAF 116/296 reads (39%) | catalogued as COSV53117706; called by muse, varscan2
- GSDME | c.354G>A p.L118= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV61652967; called by muse, mutect2, varscan2
- GSS | c.993C>G p.L331= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV53623551, COSV53628484; called by muse, varscan2
- HCK | c.1035G>A p.L345= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV52940594; called by muse, mutect2, varscan2
- HDAC10 | c.1141C>T p.L381= | Silent (SNP) | VAF 26/36 reads (72%) | catalogued as rs766106095, COSV50588390; called by muse, mutect2, varscan2
- HMOX2 | c.831G>C p.L277= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV54861858; called by muse, mutect2, varscan2
- HSF1 | c.792C>A p.I264= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV60049397; called by muse, mutect2, varscan2
- IFFO1 | c.291G>C p.R97= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs1302405198, COSV59113717; called by muse, varscan2
- IFFO1 | c.240G>C p.L80= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV59113721; called by muse, varscan2
- IGSF9B | c.2466G>A p.K822= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs1440203537, COSV58073053; called by muse, varscan2
- IL17RD | c.1068G>A p.P356= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs368786454; ClinVar: likely benign; called by mutect2, varscan2
- INTS2 | c.2979T>A p.V993= | Silent (SNP) | VAF 59/183 reads (32%) | catalogued as COSV52156847; called by muse, mutect2, varscan2
- KALRN | c.4599G>A p.V1533= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV53780969; called by muse, mutect2, varscan2
- KAT14 | c.1869G>A p.L623= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV66609392; called by muse, mutect2, varscan2
- KCNH2 | c.1668C>A p.T556= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs748266308, COSV51230308; called by muse, mutect2, varscan2
- KLK9 | c.522C>G p.L174= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV51594777; called by muse, mutect2
- KMT2A | c.7044C>T p.I2348= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs780538462, COSV63281812; called by muse, mutect2, varscan2
- KPNA4 | c.552C>A p.I184= | Silent (SNP) | VAF 44/114 reads (39%) | catalogued as rs1377532667, COSV62077066; called by muse, mutect2, varscan2
- KRCC1 | c.354G>C p.L118= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as COSV61252319; called by muse, mutect2, varscan2
- LINGO2 | c.249G>A p.L83= | Silent (SNP) | VAF 52/143 reads (36%) | catalogued as COSV58064760; called by muse, mutect2, varscan2
- LRCH4 | c.1926G>C p.V642= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99776271; called by muse, mutect2, varscan2
- LRRC8E | c.1107C>T p.L369= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs1402236119, COSV60719324; called by muse, mutect2, varscan2
- MAGI2 | c.1269A>C p.T423= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV62700342; called by muse, mutect2, varscan2
- MAP3K21 | c.1611G>A p.L537= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV64042685; called by muse, mutect2, varscan2
- METTL3 | c.1191C>G p.P397= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs1312066155, COSV52971428; called by muse, mutect2, varscan2
- MFSD3 | c.903C>G p.V301= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV56743295, COSV56743997; called by muse, mutect2, varscan2
- MGA | c.4185G>A p.V1395= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV54963548; called by muse, mutect2, varscan2
- MINDY1 | c.768G>C p.L256= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV56501020; called by muse, mutect2, varscan2
- MPDZ | c.864A>C p.G288= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV59954395; called by muse, mutect2, varscan2
- MSH2 | c.2058A>T p.V686= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as COSV51885159; called by muse, mutect2, varscan2
- MYO7B | c.1584G>C p.L528= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV67352203; called by muse, mutect2, varscan2
- MYO7B | c.2241G>A p.L747= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as COSV67352206; called by muse, mutect2, varscan2
- NDUFAB1 | c.267C>G p.L89= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as COSV50287704; called by muse, mutect2, varscan2
- NOP2 | c.1221G>A p.K407= (on ENST00000322166 / NM_001258308.2; = p.K403= on NM_006170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV59113761; called by muse, mutect2, varscan2
- NOS1AP | c.744C>G p.G248= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV62640388; called by muse, varscan2
- NPHS1 | c.1053G>A p.Q351= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV62289950; called by muse, mutect2, varscan2
- NUP210 | c.3822C>T p.L1274= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV54414356; called by muse, mutect2, varscan2
- NUP42 | c.996G>C p.V332= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as COSV51731293; called by muse, mutect2, varscan2
- ODC1 | c.1209G>T p.P403= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV52173640; called by muse, mutect2, varscan2
- OR2A7 | c.552C>T p.L184= | Silent (SNP) | VAF 24/166 reads (14%) | catalogued as COSV101512233; called by muse, mutect2, varscan2
- PARP10 | c.162C>T p.L54= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as rs949764974, COSV57300212, COSV57300263; called by muse, mutect2, varscan2
- PCDHB15 | c.2103C>T p.F701= | Silent (SNP) | VAF 75/146 reads (51%) | catalogued as COSV51424990; called by muse, mutect2, varscan2
- PFKFB3 | c.1368C>T p.L456= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as rs1434146965, COSV57993355; called by muse, mutect2, varscan2
- PIK3C2A | c.1485C>T p.N495= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as COSV56407127; called by muse, mutect2, varscan2
- PIK3R4 | c.2151C>G p.L717= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV63243983; called by muse, mutect2, varscan2
- PLEKHH3 | c.504G>A p.V168= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs367975453; called by muse, mutect2, varscan2
- PLLP | c.480C>T p.F160= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV54656851; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.2352G>T p.P784= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV53456138; called by muse, mutect2, varscan2
- PPFIA3 | c.480C>T p.F160= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs767117196, COSV61951433; called by muse, mutect2, varscan2
- PPM1G | c.1506C>T p.I502= | Silent (SNP) | VAF 26/137 reads (19%) | catalogued as COSV52010903; called by muse, mutect2, varscan2
- PRKCA | c.120C>A p.I40= | Silent (SNP) | VAF 44/147 reads (30%) | catalogued as COSV52584352; called by muse, mutect2, varscan2
- PRKD2 | c.69C>T p.P23= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs766687958, COSV52189875; called by muse, mutect2, varscan2
- PRRC2A | c.2055G>A p.V685= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV65689095; called by muse, mutect2, varscan2
- PSG5 | c.39C>A p.I13= | Silent (SNP) | VAF 45/163 reads (28%) | catalogued as rs549326708, COSV61654950, COSV61655425; called by muse, mutect2, varscan2
- PTCD1 | c.12G>C p.V4= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs373379334; called by muse, mutect2, varscan2
- QRFPR | c.687G>A p.V229= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs776518040, COSV57680216; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1647C>G p.L549= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV57929581, COSV57933193; called by muse, mutect2, varscan2
- RBMX2 | c.726G>T p.L242= | Silent (SNP) | VAF 18/21 reads (86%) | catalogued as COSV59730047; called by muse, mutect2, varscan2
- RIPK1 | c.615C>A p.P205= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV52531873; called by muse, mutect2, varscan2
- RXRA | c.1008C>T p.S336= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as rs759299186, COSV62685544; called by muse, mutect2, varscan2
- SBF1 | c.2769C>T p.L923= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs1312128477, COSV62370504; called by muse, mutect2, varscan2
- SLC12A4 | c.2695C>T p.L899= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV50455475; called by muse, mutect2, varscan2
- SLC20A2 | c.1422G>A p.E474= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV60607219; called by muse, mutect2, varscan2
- SLC2A5 | c.307C>T p.L103= | Silent (SNP) | VAF 56/176 reads (32%) | catalogued as COSV66238120; called by muse, mutect2, varscan2
- SLC44A4 | c.1539G>A p.Q513= | Silent (SNP) | VAF 52/106 reads (49%) | catalogued as COSV57669207; called by muse, mutect2, varscan2
- SMARCD1 | c.834G>C p.V278= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV67413223; called by muse, mutect2, varscan2
- SORBS1 | c.2562G>A p.E854= (on ENST00000361941 / NM_001034954.2; = p.E504= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as COSV53365772; called by muse, mutect2, varscan2
- SPATA45 | c.132G>A p.L44= | Silent (SNP) | VAF 40/146 reads (27%) | catalogued as COSV60571542; called by muse, mutect2
- SPON1 | c.733C>T p.L245= | Silent (SNP) | VAF 4/86 reads (5%) | catalogued as rs1458589751, COSV100116428, COSV59959151; called by muse, mutect2
- SPTA1 | c.906G>C p.L302= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV63759861; called by muse, mutect2
- SRGAP3 | c.414C>G p.L138= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV64540273; called by muse, mutect2, varscan2
- SRSF12 | c.567C>T p.S189= | Silent (SNP) | VAF 86/244 reads (35%) | catalogued as COSV71683794; called by muse, mutect2, varscan2
- SSH1 | c.2853G>A p.V951= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as rs1304486407, COSV58460534; called by muse, mutect2, varscan2
- TAZ | c.714G>C p.L238= | Silent (SNP) | VAF 40/58 reads (69%) | catalogued as COSV54797484; called by muse, mutect2, varscan2
- TFAP2E | c.606G>A p.L202= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs188592363; called by muse, mutect2
- THSD7A | c.2001C>A p.A667= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs1484815302, COSV70273259; called by muse, mutect2, varscan2
- TLE2 | c.1617C>T p.I539= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs896496463, COSV53578777; called by muse, mutect2, varscan2
- TMEM65 | c.366G>A p.A122= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs532224599, COSV52632339; called by muse, mutect2
- TNFRSF10B | c.732G>A p.L244= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV52393044; called by muse, mutect2, varscan2
- TOX3 | c.798C>T p.F266= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV54873536; called by muse, mutect2, varscan2
- TP53TG5 | c.174G>A p.R58= | Silent (SNP) | VAF 90/310 reads (29%) | catalogued as COSV65578294; called by muse, mutect2, varscan2
- TRAPPC6A | c.52C>T p.L18= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs1397569342, COSV50065572; called by muse, mutect2, varscan2
- TTLL4 | c.1998C>T p.F666= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs777738648, COSV51439600; called by muse, mutect2, varscan2
- TUBB1 | c.726C>T p.F242= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV53888426; called by muse, mutect2, varscan2
- UAP1 | c.534C>T p.F178= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs555399203, COSV54849623; called by muse, mutect2, varscan2
- UBE3B | c.2271G>A p.E757= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs1268340286, COSV55099066; called by muse, mutect2, varscan2
- UGGT2 | c.634C>T p.L212= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as rs1280114123, COSV65025716, COSV65026073; called by muse, mutect2, varscan2
- USP35 | c.2613T>A p.A871= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as COSV60871189; called by muse, mutect2, varscan2
- UTP6 | c.1533C>T p.F511= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV55571215, COSV55573021, COSV55575833; called by muse, mutect2, varscan2
- VMO1 | c.174C>T p.F58= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs1177509492, COSV54497258, COSV54498076; called by muse, mutect2, varscan2
- WDFY3 | c.7953C>G p.V2651= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV55714217; called by muse, varscan2
- WDR7 | c.3627C>T p.F1209= | Silent (SNP) | VAF 38/71 reads (54%) | catalogued as COSV54363731, COSV99589219; called by muse, mutect2, varscan2
- WHRN | c.232C>T p.L78= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV54335102; called by muse, mutect2, varscan2
- ZIM2 | c.483G>T p.P161= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV55648340; called by muse, mutect2, varscan2
- ZNF17 | c.1455G>A p.L485= | Silent (SNP) | VAF 62/186 reads (33%) | catalogued as COSV56922625; called by muse, mutect2, varscan2
- ANKRD13D | c.*513G>A | 3'UTR (SNP) | VAF 13/47 reads (28%) | catalogued as COSV57754792; called by muse, mutect2, varscan2
- ARHGAP42 | c.*3733G>A | 3'UTR (SNP) | VAF 30/116 reads (26%) | catalogued as rs752162993, COSV53987224; called by muse, mutect2, varscan2
- MIB1 | c.1829+6108G>C | Intron (SNP) | VAF 78/124 reads (63%) | catalogued as COSV99839214; called by muse, mutect2, varscan2
- NACA | c.70+4299A>T | Intron (SNP) | VAF 23/78 reads (29%) | catalogued as COSV63273078; called by muse, mutect2, varscan2
- NBPF11 | c.-548-2876C>G | Intron (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- PHGDH | c.*7C>T | 3'UTR (SNP) | VAF 22/89 reads (25%) | catalogued as COSV101024683, COSV65569361; called by muse, mutect2, varscan2
- SNORD3B-1 | n.200G>C | RNA (SNP) | VAF 22/174 reads (13%) | catalogued as rs201700670; called by muse, varscan2
- SUCO | chr1:172532573 C>T | 5'Flank (SNP) | VAF 15/43 reads (35%) | catalogued as COSV55271587; called by muse, mutect2, varscan2
- TTC7B | c.-1G>A | 5'UTR (SNP) | VAF 8/18 reads (44%) | catalogued as rs1235693918, COSV100128339; called by muse, mutect2
- UBAC2 | c.31+509G>A | Intron (SNP) | VAF 23/68 reads (34%) | catalogued as COSV63121808; called by muse, mutect2, varscan2
